CPTAC case C3L-00792 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/022c3490-811c-4f82-ad9b-8004a3df7e5c

Demographics
Sex at birth: female; Race: white; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 0 days; Progression or recurrence: no; Days to last follow up: 0 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 8.7 cm (a second GDC size field records 1.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Indeterminate; Sarcomatoid present: No.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,094 days (3.0 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 85.73 kg; Height: 170.18 cm; BMI: 29.6; Comorbidities: Congestive Heart Failure (CHF); Diabetes treatment type: Insulin.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00792-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 200 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00792-21: Section location: Lower pole; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3L-00792-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-00792-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
